Somatic mutation profile of tumor specimen TCGA-AX-A1C7-01A (aliquot TCGA-AX-A1C7-01A-11D-A135-09) from TCGA case TCGA-AX-A1C7, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 77.2 years (28,198 days).
Specimen TCGA-AX-A1C7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) edffc5aa-d1d7-4d54-a044-2b2b812f4447.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A1C7-10A (Blood Derived Normal), aliquot TCGA-AX-A1C7-10A-01D-A135-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb8a0c66-d109-4549-8738-31d536314c98

The open-access MAF lists 52 somatic variants for this specimen: 40 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 10, Intron 2, Splice Site 2, Nonsense Mutation 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1268G>T p.G423V (on ENST00000281708 / NM_001349798.2; = p.G343V on NM_018315.5) | Missense Mutation (SNP) | VAF 54/122 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157879635, COSV55892390, COSV99657129; called by muse, mutect2, varscan2
- AOC3 | c.1142C>T p.T381M | Missense Mutation (SNP) | VAF 20/22 reads (91%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs755447601, COSV53826946; called by muse, mutect2, varscan2
- ASB12 | c.135C>A p.D45E | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1308775858, COSV62857013; called by muse, mutect2, varscan2
- ATP1A2 | c.2115+1G>A p.X705_splice | Splice Site (SNP) | VAF 12/58 reads (21%) | catalogued as COSV63403991; called by muse, varscan2
- BLM | c.3559G>T p.V1187L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV61924421; called by muse, mutect2, varscan2
- CACNA1G | c.2537G>A p.R846H | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61729013; called by muse, mutect2, varscan2
- EFCC1 | c.1598C>T p.S533L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs267599600, COSV71401778; called by muse, mutect2, varscan2
- GEN1 | c.2248G>T p.V750F | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as rs1047211166, COSV58056799; called by muse, mutect2, varscan2
- HEATR5B | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 49/87 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.498); catalogued as rs775104970, COSV51853366; called by muse, mutect2, varscan2
- IL1RAPL1 | c.407G>A p.G136D | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.164); catalogued as COSV56265477; called by muse, mutect2, varscan2
- KCNN2 | c.505G>C p.A169P (on ENST00000264773; = p.A381P on NM_021614.4) | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV53289563, COSV53290646; called by muse, mutect2, varscan2
- KIAA1217 | c.2131A>T p.R711* | Nonsense Mutation (SNP) | VAF 21/51 reads (41%) | catalogued as COSV56817357; called by muse, mutect2, varscan2
- KLK6 | c.40+2T>C p.X14_splice | Splice Site (SNP) | VAF 29/66 reads (44%) | catalogued as COSV59565754; called by muse, mutect2, varscan2
- LRFN4 | c.1496C>G p.T499R | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58921780; called by muse, mutect2, varscan2
- LRRIQ4 | c.1143A>C p.Q381H | Missense Mutation (SNP) | VAF 42/66 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV61619339; called by muse, mutect2, varscan2
- MACF1 | c.8479G>A p.A2827T | Missense Mutation (SNP) | VAF 18/49 reads (37%) | catalogued as COSV57111153; called by muse, mutect2, varscan2
- MAP9 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs188784938, COSV60904896; called by muse, mutect2, varscan2
- MCC | c.2227G>T p.A743S | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV56729638; called by muse, mutect2, varscan2
- MFSD2A | c.516G>C p.T172= (on ENST00000372809 / NM_001136493.3; = p.T159= on NM_032793.5 and 3 other RefSeq transcripts) | Splice Region (SNP) | VAF 34/76 reads (45%) | catalogued as COSV65685719; called by muse, mutect2, varscan2
- NBEA | c.5758C>A p.Q1920K | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV59788500; called by muse, mutect2, varscan2
- OR5P2 | c.557C>G p.S186C | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1171384687, COSV61490601; called by muse, mutect2, varscan2
- PCDH12 | c.1173C>A p.C391* | Nonsense Mutation (SNP) | VAF 23/50 reads (46%) | catalogued as COSV51521737; called by muse, mutect2, varscan2
- PCDH12 | c.1172G>A p.C391Y | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV51521751; called by muse, mutect2, varscan2
- PCDHA1 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); catalogued as COSV65372518; called by muse, mutect2
- PDZD2 | c.7522G>A p.V2508M | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as rs377748174; called by muse, mutect2, varscan2
- PIGR | c.2159A>G p.E720G | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.554); catalogued as COSV62904182; called by muse, mutect2, varscan2
- PLA2G2E | c.211C>A p.R71S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.155); catalogued as rs780494033, COSV64290582; called by muse, mutect2, varscan2
- PLCL1 | c.3233G>A p.R1078H | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.862); catalogued as rs201915547; called by muse, mutect2, varscan2
- RADX | c.2530T>A p.Y844N | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as COSV65318784; called by muse, mutect2, varscan2
- SCML2 | c.1705G>T p.V569F | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT tolerated (0.26); PolyPhen benign (0.052); catalogued as COSV52621461; called by muse, mutect2, varscan2
- SEMA3G | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated (0.39); PolyPhen benign (0.062); catalogued as rs147355742; called by muse, mutect2, varscan2
- TDP2 | c.611T>G p.M204R | Missense Mutation (SNP) | VAF 82/262 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV61967398; called by muse, mutect2, varscan2
- THAP4 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.223); catalogued as rs777843641, COSV67191686; called by muse, mutect2, varscan2
- TMEM132D | c.2698G>A p.E900K | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.017); catalogued as rs1457475558, COSV67161039; called by muse, mutect2
- TMPRSS11E | c.568C>T p.L190F | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.541); catalogued as COSV59519383, COSV59520041; called by muse, mutect2, varscan2
- TRAV8-4 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.89); PolyPhen benign (0.069); catalogued as rs534986740; called by muse, mutect2, varscan2
- USP34 | c.9640G>A p.A3214T | Missense Mutation (SNP) | VAF 73/138 reads (53%) | SIFT tolerated (0.75); PolyPhen benign (0.086); catalogued as rs753423982, COSV63725083; called by muse, mutect2, varscan2
- VSIG10 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as rs1305799434, COSV63653528; called by muse, mutect2, varscan2
- WTIP | c.1184G>T p.G395V | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54330776, COSV99542494; called by muse, mutect2, varscan2
- GNL3 | c.206_210dup p.L71Rfs*6 | Frame Shift Ins (INS) | VAF 14/34 reads (41%) | called by mutect2, pindel, varscan2
- DPP10 | c.1569A>G p.E523= | Silent (SNP) | VAF 49/89 reads (55%) | catalogued as COSV59690104; called by muse, mutect2, varscan2
- HRNR | c.780C>T p.H260= | Silent (SNP) | VAF 70/149 reads (47%) | catalogued as rs139159585, COSV64256801; called by muse, mutect2, varscan2
- MAGEB10 | c.651T>C p.C217= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as COSV63311471; called by muse, mutect2, varscan2
- MUC16 | c.32478G>A p.T10826= | Silent (SNP) | VAF 39/40 reads (98%) | catalogued as rs774569415, COSV67469407; called by muse, mutect2, varscan2
- SEPTIN11 | c.642T>C p.F214= | Silent (SNP) | VAF 38/76 reads (50%) | catalogued as COSV53582556; called by muse, mutect2, varscan2
- SMAD1 | c.666G>A p.T222= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as rs752874837, COSV57471494; called by muse, mutect2, varscan2
- TELO2 | c.94C>T p.L32= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as rs762117786, COSV51978442; called by muse, mutect2, varscan2
- TRIM61 | c.36A>G p.A12= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV61418238; called by muse, mutect2, varscan2
- VIRMA | c.4164G>A p.K1388= | Silent (SNP) | VAF 50/52 reads (96%) | catalogued as COSV52585716; called by muse, mutect2, varscan2
- ZNF677 | c.57A>G p.Q19= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as COSV61720391; called by muse, mutect2, varscan2
- DST-AS1 | n.139+7403C>A | Intron (SNP) | VAF 29/56 reads (52%) | catalogued as COSV100880898, COSV66097045; called by muse, mutect2, varscan2
- PDE4B | c.635-20G>A | Intron (SNP) | VAF 31/73 reads (42%) | catalogued as COSV58478839; called by muse, mutect2, varscan2
